Gene-level copy-number profile of tumor specimen TCGA-CF-A1HS-01A from TCGA case TCGA-CF-A1HS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.5 years (27,565 days).
Specimen TCGA-CF-A1HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6026d665-e5ff-4c6b-89e2-41caddb39158.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CF-A1HS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ccdd0f9-cccd-4e05-a7aa-391485a26902

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 499; copy number 2: 24,743; copy number 3: 18,308; copy number 4: 13,670; copy number 5: 525; copy number 6: 677; copy number 7: 251; copy number 8: 104; copy number 9: 261; copy number 10: 420; copy number 11: 100; copy number 12: 9; copy number 13: 35; copy number 14: 32; copy number 15: 22; copy number 19: 26; copy number 20: 15; copy number 21: 2; copy number 23: 43; copy number 25: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CF-A1HS-01A-11D-A13V-01): tumor purity 0.54, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,587 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,193,619–44,651,724, 208 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr1:46,632,737–48,497,736, 52 genes, copy number 5 (within-gene range 3–5): ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1, CYP4B1, CYP4Z2P, TUBAP8, CYP4A11, CYP4A26P, CYP4A43P, CYP4A27P, CYP4A44P, CYP4X1, CYP4Z1, TUBAP9, CYP4A22-AS1, CYP4A22, MTND1P34, LINC00853, PDZK1IP1, TAL1, AL135960.1, STIL, CMPK1, LINC01389, FOXE3, FOXD2-AS1, FOXD2, AL356458.1, RPL21P24, ATP6V0E1P4, LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1.
- chr1:48,552,991–49,269,285, 5 genes, copy number 5: AL391844.1, BEND5, AL645507.1, AC099788.1, AGBL4-AS1.
- chr1:51,789,191–53,738,106, 77 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:54,779,712–55,324,691, 16 genes, copy number 6: TTC22, AC096536.1, LEXM, DHCR24, AC096536.3, AC096536.2, DHCR24-DT, AL590440.2, TMEM61, AL590440.1, BSND, PCSK9, USP24, MIR4422HG, GYG1P3, MIR4422.
- chr1:55,367,466–55,484,972, 5 genes, copy number 6: GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA.
- chr1:56,145,721–56,524,495, 5 genes, copy number 7 (within-gene range 3–7): AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767.
- chr1:84,785,427–85,264,402, 10 genes, copy number 5: AC104169.1, LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA.
- chr2:101,479,390–102,179,874, 10 genes, copy number 5–9 (within-gene range 3–9): LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1.
- chr2:141,167,257–141,208,376, 2 genes, copy number 9: RNU6-904P, RPS16P3.
- chr3:63,228,315–75,785,583, 171 genes, copy number 13–25 (within-gene range 1–25) (broad region; genes not listed).
- chr3:75,964,980–76,435,428, 2 genes, copy number 13: Y_RNA, CAP1P1.
- chr5:58,198–45,895,970, 709 genes, copy number 6–10 (broad region; genes not listed).
- chr6:18,120,440–18,273,266, 5 genes, copy number 8: NHLRC1, TPMT, KDM1B, DEK, Y_RNA.
- chr6:19,143,695–19,321,021, 2 genes, copy number 9: AL589647.1, AL357052.1.
- chr6:19,348,181–19,349,076, 1 gene, copy number 9: RPL5P20.
- chr6:19,837,370–23,031,780, 34 genes, copy number 10–15: ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1.
- chr6:38,168,451–38,640,148, 3 genes, copy number 12 (within-gene range 3–21): BTBD9, AL033518.1, BTBD9-AS1.
- chr6:38,675,925–39,030,792, 8 genes, copy number 12–21 (within-gene range 3–21): GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1.
- chr6:43,605,316–43,842,625, 9 genes, copy number 6 (within-gene range 3–6): GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2.
- chr8:31,827,238–32,139,495, 2 genes, copy number 5: AC068931.1, NRG1-IT1.
- chr8:32,911,493–33,600,023, 19 genes, copy number 5–8: RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26.
- chr8:33,641,581–33,723,079, 3 genes, copy number 5: BUD31P1, RN7SL457P, VENTXP5.
- chr10:55,247,755–70,284,004, 182 genes, copy number 5 (broad region; genes not listed).
- chr12:113,789,542–115,718,013, 33 genes, copy number 5: DYNLL1P4, RBM19, AC009731.1, AC073863.1, AC010183.1, AC010183.2, HAUS8P1, GLULP5, LINC02459, TBX5, TBX5-AS1, RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2, AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2, AC009803.2, AC009803.1, UBA52P7, RN7SL865P.
- chr13:73,036,401–73,661,891, 10 genes, copy number 6 (within-gene range 4–6): PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr13:83,877,205–114,337,626, 414 genes, copy number 6 (broad region; genes not listed).
- chr15:22,773,063–22,869,362, 2 genes, copy number 6 (within-gene range 3–6): NIPA1, NIPA2.
- chr16:63,703,483–63,703,665, 1 gene, copy number 5: AC018846.1.
- chr16:71,281,389–76,928,169, 153 genes, copy number 5–11 (broad region; genes not listed).
- chr17:27,651,334–29,057,216, 106 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr17:32,039,974–32,906,584, 43 genes, copy number 23: SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, AC026620.2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2.
- chr19:37,312,837–37,369,365, 1 gene, copy number 7 (within-gene range 4–7): ZNF875.
- chr19:37,371,061–40,629,818, 165 genes, copy number 7–11 (broad region; genes not listed).
- chr20:31,257,664–34,311,802, 119 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 499. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
